Somatic mutation profile of tumor specimen C3L-01160-01 (aliquot CPT0170600018) from CPTAC case C3L-01160, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 60.3 years (22,041 days).
Specimen C3L-01160-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 62145916-750f-4f36-b1a4-dcd568f76089.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01160-31 (Blood Derived Normal), aliquot CPT0167290002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64b85e44-e8e4-4464-8135-f7c02284c05f

The open-access MAF lists 86 somatic variants for this specimen: 58 protein-altering or splice-affecting, 18 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 18, Nonsense Mutation 8, Intron 4, 5'UTR 3, RNA 2, Frame Shift Ins 1, 3'Flank 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 1179/2235 reads (53%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.9961C>T p.R3321* | Nonsense Mutation (SNP) | VAF 216/383 reads (56%) | catalogued as rs793888512, CM105475, COSV56410587; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 580/1120 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375G>A p.T125= | Splice Region (SNP) | VAF 93/353 reads (26%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANKRD30B | c.3807T>A p.C1269* | Nonsense Mutation (SNP) | VAF 573/979 reads (59%) | catalogued as COSV100271343; called by muse, mutect2, varscan2
- CD53 | c.18G>C p.L6F | Missense Mutation (SNP) | VAF 151/707 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV54759950; called by muse, mutect2, varscan2
- CDYL2 | c.757G>A p.V253I | Missense Mutation (SNP) | VAF 114/830 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.941); catalogued as rs62049900, COSV101629539; called by muse, mutect2, varscan2
- CILP2 | c.2334G>A p.W778* | Nonsense Mutation (SNP) | VAF 155/419 reads (37%) | catalogued as rs1174381528; called by muse, mutect2, varscan2
- EPHA6 | c.1039G>A p.D347N | Missense Mutation (SNP) | VAF 89/410 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs762397948; called by muse, mutect2, varscan2
- GPR55 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 208/773 reads (27%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs766293332, COSV101235720; called by muse, mutect2, varscan2
- ITPR3 | c.2251A>G p.I751V | Missense Mutation (SNP) | VAF 279/1134 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.101); catalogued as COSV65413683; called by muse, mutect2, varscan2
- NOTCH1 | c.3407G>A p.G1136D | Missense Mutation (SNP) | VAF 373/1415 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs1394605454, COSV53076903; called by muse, mutect2, varscan2
- OBSCN | c.17386G>A p.V5796I | Missense Mutation (SNP) | VAF 385/936 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); catalogued as rs761881774; called by muse, mutect2, varscan2
- OR4C15 | c.883T>A p.S295T (on ENST00000314644; = p.S241T on NM_001001920.2) | Missense Mutation (SNP) | VAF 108/455 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.169); catalogued as rs553077311; called by muse, mutect2, varscan2
- OTOG | c.4931C>T p.T1644M | Missense Mutation (SNP) | VAF 115/395 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs781263629; called by muse, mutect2, varscan2
- PDZD7 | c.490C>T p.R164W | Missense Mutation (SNP) | VAF 206/920 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs200664140, COSV64646917; called by muse, varscan2
- PGBD1 | c.246G>C p.Q82H | Missense Mutation (SNP) | VAF 125/539 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.89); catalogued as rs1341479537; called by muse, mutect2, varscan2
- SHROOM2 | c.436C>T p.R146* | Nonsense Mutation (SNP) | VAF 109/375 reads (29%) | catalogued as rs770261260, COSV66607764; called by muse, mutect2, varscan2
- SLC39A12 | c.1238C>G p.S413C | Missense Mutation (SNP) | VAF 143/545 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV66194540; called by muse, mutect2, varscan2
- SMAD4 | c.780C>A p.Y260* | Nonsense Mutation (SNP) | VAF 318/937 reads (34%) | catalogued as COSV61685105; called by muse, mutect2, varscan2
- SMG5 | c.1334G>A p.G445D | Missense Mutation (SNP) | VAF 200/869 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs778890387; called by muse, mutect2, varscan2
- SOX5 | c.1118G>A p.S373N | Missense Mutation (SNP) | VAF 608/1237 reads (49%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs1253562639; called by muse, mutect2, varscan2
- STARD9 | c.8072C>A p.P2691Q | Missense Mutation (SNP) | VAF 132/526 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV51915339; called by muse, mutect2, varscan2
- SULF1 | c.1195C>T p.R399* | Nonsense Mutation (SNP) | VAF 104/507 reads (21%) | catalogued as rs1563576026, COSV52676256; called by muse, mutect2, varscan2
- TRPA1 | c.1238G>T p.G413V | Missense Mutation (SNP) | VAF 230/1043 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100085491; called by muse, mutect2, varscan2
- TRPA1 | c.1237G>A p.G413R | Missense Mutation (SNP) | VAF 229/1039 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51574441; called by muse, mutect2, varscan2
- TTI1 | c.1999A>G p.I667V | Missense Mutation (SNP) | VAF 194/703 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.137); catalogued as rs780394309; called by muse, mutect2, varscan2
- UBN2 | c.1604G>T p.R535L | Missense Mutation (SNP) | VAF 63/271 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as rs747342378; called by muse, mutect2, varscan2
- ABCB7 | c.1721C>T p.S574L (on ENST00000373394 / NM_001271696.3; = p.S575L on NM_004299.6) | Missense Mutation (SNP) | VAF 145/623 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- ADCY10 | c.2360A>C p.D787A | Missense Mutation (SNP) | VAF 127/838 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- AKAP8 | c.943G>C p.D315H | Missense Mutation (SNP) | VAF 247/691 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATG5 | c.316-1G>C p.X106_splice | Splice Site (SNP) | VAF 17/45 reads (38%) | called by muse, mutect2, varscan2
- ATP2B1 | c.569A>G p.Q190R | Missense Mutation (SNP) | VAF 262/858 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CAPN7 | c.191T>G p.V64G | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- CECR2 | c.1336G>C p.V446L (on ENST00000342247 / NM_001290047.2; = p.V263L on NM_001290046.1) | Missense Mutation (SNP) | VAF 133/525 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- CPNE9 | c.582dup p.T195Hfs*22 | Frame Shift Ins (INS) | VAF 77/511 reads (15%) | called by mutect2, pindel, varscan2
- DGKI | c.1737T>A p.D579E | Missense Mutation (SNP) | VAF 93/434 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAT3 | c.3391A>T p.T1131S | Missense Mutation (SNP) | VAF 209/874 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- GCSAML | c.313A>G p.R105G | Missense Mutation (SNP) | VAF 200/1158 reads (17%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- GUF1 | c.1638C>G p.Y546* | Nonsense Mutation (SNP) | VAF 137/735 reads (19%) | called by muse, mutect2, varscan2
- LONRF3 | c.1042A>G p.R348G | Missense Mutation (SNP) | VAF 79/334 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- MAGEC3 | c.924G>C p.L308F | Missense Mutation (SNP) | VAF 76/294 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- MAP7D3 | c.1591A>C p.K531Q | Missense Mutation (SNP) | VAF 69/400 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- MARVELD3 | c.1102G>T p.A368S | Missense Mutation (SNP) | VAF 80/578 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- MLIP | c.728A>G p.N243S | Missense Mutation (SNP) | VAF 93/429 reads (22%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- NAP1L2 | c.1034C>G p.T345S | Missense Mutation (SNP) | VAF 100/367 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OR1L3 | c.860T>G p.F287C | Missense Mutation (SNP) | VAF 77/387 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- OR5J2 | c.578C>A p.S193Y | Missense Mutation (SNP) | VAF 162/644 reads (25%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- PSD2 | c.1772A>G p.N591S | Missense Mutation (SNP) | VAF 88/351 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- SHANK1 | c.3943G>A p.A1315T | Missense Mutation (SNP) | VAF 119/421 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- SNCG | c.174G>C p.K58N | Missense Mutation (SNP) | VAF 78/491 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SRBD1 | c.2818G>A p.V940M | Missense Mutation (SNP) | VAF 201/906 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TEKT4 | c.740A>C p.K247T | Missense Mutation (SNP) | VAF 159/594 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- TMC2 | c.1024T>C p.F342L | Missense Mutation (SNP) | VAF 102/499 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- TTC27 | c.1611T>A p.H537Q | Missense Mutation (SNP) | VAF 327/1416 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- UBN2 | c.1405C>G p.L469V | Missense Mutation (SNP) | VAF 31/222 reads (14%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- ZNF268 | c.487G>C p.D163H | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- ZNF521 | c.2182C>A p.Q728K | Missense Mutation (SNP) | VAF 143/387 reads (37%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANKFN1 | c.3282C>T p.D1094= (on ENST00000653862; = p.D947= on NM_001365758.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 807/1620 reads (50%) | catalogued as rs996720759; called by muse, mutect2, varscan2
- ASF1B | c.291C>T p.I97= | Silent (SNP) | VAF 121/709 reads (17%) | called by muse, mutect2, varscan2
- CCDC184 | c.151C>T p.L51= | Silent (SNP) | VAF 254/903 reads (28%) | called by muse, mutect2, varscan2
- CSMD1 | c.9525G>A p.K3175= (on ENST00000520002; = p.K3174= on NM_033225.6) | Silent (SNP) | VAF 76/414 reads (18%) | called by muse, mutect2, varscan2
- EPHA6 | c.1038T>A p.A346= | Silent (SNP) | VAF 90/416 reads (22%) | called by muse, mutect2, varscan2
- FMN2 | c.862C>A p.R288= | Silent (SNP) | VAF 13/402 reads (3%) | catalogued as COSV100144696; called by muse, mutect2
- GLI3 | c.315C>T p.R105= | Silent (SNP) | VAF 160/600 reads (27%) | catalogued as rs140872736; ClinVar: likely benign; called by muse, mutect2, varscan2
- ITGA1 | c.873G>A p.K291= | Silent (SNP) | VAF 43/193 reads (22%) | called by muse, mutect2, varscan2
- LRRK2 | c.3621T>C p.D1207= | Silent (SNP) | VAF 88/305 reads (29%) | called by muse, mutect2, varscan2
- OR52A5 | c.427T>C p.L143= | Silent (SNP) | VAF 59/318 reads (19%) | catalogued as COSV56613991, COSV56614404; called by muse, mutect2, varscan2
- OR5J2 | c.579C>A p.S193= | Silent (SNP) | VAF 165/658 reads (25%) | called by muse, mutect2, varscan2
- OR5M1 | c.273C>A p.T91= | Silent (SNP) | VAF 256/1097 reads (23%) | called by muse, mutect2, varscan2
- PRAF2 | c.27A>T p.L9= | Silent (SNP) | VAF 134/591 reads (23%) | called by muse, mutect2, varscan2
- SHISA7 | c.42C>G p.A14= | Silent (SNP) | VAF 64/385 reads (17%) | called by muse, mutect2, varscan2
- SLITRK1 | c.309G>T p.L103= | Silent (SNP) | VAF 242/655 reads (37%) | called by muse, mutect2, varscan2
- TMEM108 | c.396C>T p.R132= | Silent (SNP) | VAF 186/709 reads (26%) | called by muse, mutect2, varscan2
- TRO | c.3741T>A p.A1247= | Silent (SNP) | VAF 168/579 reads (29%) | called by muse, mutect2, varscan2
- ZNF581 | c.78G>T p.R26= | Silent (SNP) | VAF 65/251 reads (26%) | called by muse, mutect2, varscan2
- AMPH | c.1182+1304A>C | Intron (SNP) | VAF 84/334 reads (25%) | called by muse, mutect2, varscan2
- AP003062.1 | n.221T>C | RNA (SNP) | VAF 358/2113 reads (17%) | catalogued as rs11224150; called by muse, varscan2
- ERCC6 | c.1397+7138G>T | Intron (SNP) | VAF 72/278 reads (26%) | called by muse, mutect2, varscan2
- GSTM4 | c.112+21G>C | Intron (SNP) | VAF 386/1534 reads (25%) | catalogued as rs778580839; called by muse, mutect2, varscan2
- HAUS7 | c.384+554C>T | Intron (SNP) | VAF 47/238 reads (20%) | catalogued as rs1556983490; called by muse, mutect2, varscan2
- HRH2 | chr5:175685451 ins CATT | 3'Flank (INS) | VAF 68/340 reads (20%) | catalogued as rs1561732144; called by mutect2, varscan2
- KNCN | c.-6G>A | 5'UTR (SNP) | VAF 134/605 reads (22%) | called by muse, mutect2, varscan2
- MIRLET7A2 | n.11A>C | RNA (SNP) | VAF 28/135 reads (21%) | called by muse, mutect2, varscan2
- RPL39 | c.-20T>C | 5'UTR (SNP) | VAF 49/265 reads (18%) | called by muse, mutect2, varscan2
- TAZ | c.-15G>A | 5'UTR (SNP) | VAF 248/1273 reads (19%) | catalogued as COSV99186236; called by muse, mutect2, varscan2
